Somatic mutation profile of tumor specimen TCGA-AA-3831-01A (aliquot TCGA-AA-3831-01A-01W-0900-09) from TCGA case TCGA-AA-3831, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 66.8 years (24,411 days).
Specimen TCGA-AA-3831-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48053996-86c5-4044-a154-168a0b80b7b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3831-10A (Blood Derived Normal), aliquot TCGA-AA-3831-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35e40a56-709f-4ef8-abe0-639dbefc1a9f

The open-access MAF lists 112 somatic variants for this specimen: 93 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 17, Nonsense Mutation 5, Frame Shift Ins 4, Frame Shift Del 3, Intron 1, Splice Region 1, RNA 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EYS | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | catalogued as rs794727631, CM1211748, COSV60981344; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1745C>T p.S582L (on ENST00000281708 / NM_001349798.2; = p.S502L on NM_018315.5) | Missense Mutation (SNP) | VAF 32/43 reads (74%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV104381731, COSV55890836; called by muse, mutect2, varscan2
- NPC1 | c.3493G>A p.V1165M | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748862167, CM015193, COSV52571405; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- SMAD3 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 28/38 reads (74%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs863223740, CM158377, COSV59281245; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.333); catalogued as rs199779757, COSV55295017; called by muse, mutect2, varscan2
- ACVR1B | c.655G>T p.G219W | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57778801; called by muse, mutect2, varscan2
- ALDOC | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs747367976, COSV52025644; called by muse, mutect2, varscan2
- ANK2 | c.2116G>A p.D706N | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs753937708, COSV52176533; called by muse, mutect2, varscan2
- APLP1 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.941); catalogued as rs568306221, COSV55702927; called by muse, mutect2, varscan2
- ARHGAP24 | c.2113G>A p.E705K (on ENST00000395184 / NM_001025616.3; = p.E612K on NM_031305.3) | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs139260529; called by muse, mutect2, varscan2
- ARID1A | c.2306C>A p.S769* | Nonsense Mutation (SNP) | VAF 39/126 reads (31%) | catalogued as COSV61383777, COSV61384786; called by muse, mutect2, varscan2
- ATP9A | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs757388993, COSV58769487; called by muse, mutect2, varscan2
- C12orf42 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1443958877, COSV59384692, COSV59387329; called by muse, mutect2, varscan2
- C8orf74 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs1267914932, COSV58755007; called by muse, mutect2, varscan2
- CADPS | c.3166G>A p.D1056N | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as COSV51892624; called by muse, mutect2, varscan2
- CDC42BPB | c.225C>A p.D75E | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV63476111; called by muse, mutect2, varscan2
- CDKL5 | c.2765G>A p.R922K | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV66107192; called by muse, mutect2, varscan2
- CDON | c.3454C>T p.L1152F | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as rs1291103020, COSV55000454; called by muse, mutect2, varscan2
- CEP350 | c.3499C>A p.R1167S | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV62606797; called by muse, mutect2, varscan2
- CFAP221 | c.1960C>A p.P654T | Missense Mutation (SNP) | VAF 72/259 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs377738201; called by muse, mutect2, varscan2
- CHST8 | c.118dup p.Q40Pfs*28 | Frame Shift Ins (INS) | VAF 5/37 reads (14%) | catalogued as rs779675268; called by mutect2, varscan2
- COL22A1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs764763126, COSV57327075; called by mutect2, varscan2
- COLEC12 | c.1060G>T p.A354S | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.079); catalogued as COSV68372385; called by muse, mutect2, varscan2
- CSMD1 | c.7665G>A p.P2555= (on ENST00000520002; = p.P2554= on NM_033225.6) | Splice Region (SNP) | VAF 15/50 reads (30%) | catalogued as rs760074439, COSV59353890; called by muse, mutect2, varscan2
- CUL9 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs368734594, COSV52731860; called by muse, mutect2, varscan2
- CXCR4 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV54014858; called by muse, mutect2, varscan2
- DHH | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs781595957, COSV57202564; called by muse, mutect2, varscan2
- DHX29 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52419783; called by muse, mutect2, varscan2
- DHX38 | c.2513A>G p.D838G | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51699639; called by muse, mutect2, varscan2
- EFCAB13 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 128/172 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs759102054, COSV58950800; called by muse, mutect2, varscan2
- EIF4A2 | c.1072A>G p.I358V | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV56218040; called by muse, mutect2, varscan2
- ENPP7 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs782703540, COSV60387295; called by muse, mutect2, varscan2
- FUNDC2 | c.263T>G p.F88C | Missense Mutation (SNP) | VAF 63/112 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); catalogued as COSV65671407; called by muse, mutect2, varscan2
- GOLGA6L9 | c.1117G>C p.A373P | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1348789502; called by muse, mutect2
- HAS1 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs777058982, COSV55788668; called by muse, mutect2, varscan2
- HMGCR | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55317117; called by muse, mutect2, varscan2
- IL21R | c.1079dup p.S361Lfs*5 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | catalogued as rs754481996; called by pindel, varscan2
- IRF1 | c.757G>C p.G253R | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55377891; called by muse, mutect2, varscan2
- KDM2A | c.2422A>G p.K808E | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); catalogued as COSV58190817; called by muse, mutect2, varscan2
- KIRREL2 | c.1850A>G p.E617G | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as COSV52878518; called by muse, mutect2, varscan2
- KMT2B | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.968); catalogued as rs962331806, COSV52891673; called by muse, mutect2, varscan2
- KNL1 | c.6406G>A p.D2136N (on ENST00000346991 / NM_170589.5; = p.D2110N on NM_144508.5) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.714); catalogued as COSV61157954; called by muse, mutect2, varscan2
- KRTAP12-1 | c.210C>G p.C70W | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1264537078, COSV59971768; called by muse, mutect2, varscan2
- LRRC52 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1331070925, COSV54233033, COSV54234146; called by muse, mutect2, varscan2
- MAGI1 | c.3997G>A p.A1333T | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.994); catalogued as rs142375705; called by muse, mutect2, varscan2
- MAP1B | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 180/506 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs780650498, COSV57103118; called by muse, mutect2, varscan2
- MGAM | c.3354G>C p.M1118I | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.233); catalogued as COSV72075177; called by muse, mutect2, varscan2
- MLC1 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.992); catalogued as rs761502278, COSV61118032; called by muse, mutect2, varscan2
- NAV3 | c.6382C>G p.L2128V (on ENST00000397909 / NM_001024383.2; = p.L2106V on NM_014903.6) | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57098598; called by muse, mutect2, varscan2
- NTN4 | c.615C>A p.Y205* | Nonsense Mutation (SNP) | VAF 106/217 reads (49%) | catalogued as COSV59218818, COSV59221888; called by muse, mutect2, varscan2
- NUCB1 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 10/19 reads (53%) | catalogued as COSV54387382; called by muse, mutect2, varscan2
- NWD1 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs375674809; called by muse, mutect2, varscan2
- OR2L13 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 130/355 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs377126567, COSV63557537; called by muse, mutect2, varscan2
- PCDH9 | c.2797C>G p.P933A | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV60572652; called by muse, mutect2, varscan2
- PCDHB9 | c.1070C>A p.A357D | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); catalogued as COSV53381612; called by muse, mutect2, varscan2
- PHOX2B | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM080494, COSV56930708; called by muse, mutect2
- PRDM9 | c.1383A>T p.K461N | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as COSV57010326; called by muse, mutect2, varscan2
- RETREG2 | c.1288del p.V430Wfs*4 | Frame Shift Del (DEL) | VAF 48/159 reads (30%) | catalogued as COSV56088312; called by mutect2, pindel, varscan2
- RFTN1 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs764749726, COSV61917773, COSV61924886; called by muse, mutect2, varscan2
- RPUSD4 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs574615517, COSV53599842; called by muse, mutect2, varscan2
- RUFY4 | c.692A>T p.Q231L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV60248661; called by muse, mutect2, varscan2
- SCN1A | c.4133A>G p.N1378S (on ENST00000303395 / NM_001202435.3; = p.N1367S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CD096214, CM113328, COSV57679586; called by muse, mutect2, varscan2
- SCN5A | c.5786G>A p.R1929H (on ENST00000333535 / NM_198056.3; = p.R1928H on NM_000335.5) | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.149); catalogued as rs727504822, COSV61120723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC6A15 | c.994T>A p.F332I | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV57026833; called by muse, mutect2, varscan2
- SLC6A16 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs750477215, COSV60028283; called by muse, mutect2, varscan2
- SPATA31E1 | c.2891G>A p.C964Y | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV57793694; called by muse, mutect2, varscan2
- STAC | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs145771131; called by muse, mutect2, varscan2
- SYT14 | c.1076T>C p.V359A | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV55059474; called by muse, mutect2, varscan2
- SYT7 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.63); catalogued as rs755352659, COSV55657776; called by muse, mutect2, varscan2
- TMEM94 | c.2543G>A p.C848Y | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58596122; called by muse, varscan2
- TRMT10A | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 62/173 reads (36%) | catalogued as COSV56745713; called by muse, mutect2, varscan2
- TRPM3 | c.3357_3358insG p.F1120Vfs*3 (on ENST00000357533 / NM_001366142.2; = p.F975Vfs*3 on NM_020952.6) | Frame Shift Ins (INS) | VAF 66/287 reads (23%) | catalogued as COSV62591022; called by pindel, varscan2
- TSBP1 | c.1629+2C>T | Missense Mutation (SNP) | VAF 250/371 reads (67%) | catalogued as rs941718641, COSV66657748; called by muse, mutect2, varscan2
- TTN | c.12995A>C p.K4332T (on ENST00000591111; = p.K4286T on NM_003319.4) | Missense Mutation (SNP) | VAF 51/126 reads (40%) | catalogued as COSV60212933; called by muse, mutect2, varscan2
- TXK | c.683T>G p.I228S | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51917930; called by muse, mutect2, varscan2
- UGT2B15 | c.302T>C p.V101A | Missense Mutation (SNP) | VAF 219/637 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as COSV57735742; called by muse, mutect2, varscan2
- VCAN | c.3926C>T p.T1309M | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149651541; called by muse, mutect2, varscan2
- WDR49 | c.20C>T p.S7L (on ENST00000308378 / NM_001366158.1; = p.S348L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV57713415; called by muse, mutect2, varscan2
- WIPI2 | c.1229T>C p.V410A | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV56590242; called by muse, mutect2, varscan2
- WNT7B | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.631); catalogued as rs747437374, COSV59751412; called by muse, mutect2, varscan2
- ZC3H4 | c.341A>G p.E114G | Missense Mutation (SNP) | VAF 81/266 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV53415171; called by muse, mutect2, varscan2
- ZDBF2 | c.3740C>A p.S1247Y | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65628321; called by muse, mutect2, varscan2
- ZFPM2 | c.2309G>C p.C770S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.714); catalogued as COSV65874849; called by muse, mutect2, varscan2
- ZNF221 | c.1846G>A p.A616T | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.156); catalogued as rs770952574, COSV52110427; called by muse, mutect2, varscan2
- ZNF24 | c.1106A>T p.*369Lext*22 | Nonstop Mutation (SNP) | VAF 45/134 reads (34%) | catalogued as COSV54349025; called by muse, mutect2, varscan2
- ZNF471 | c.244A>G p.S82G | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57292582; called by muse, mutect2, varscan2
- ZNF479 | c.932C>A p.T311N | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs782010478, COSV58641339; called by muse, mutect2, varscan2
- ZNF479 | c.247G>T p.V83L | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV58641347; called by muse, mutect2, varscan2
- ZNF835 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.194); catalogued as COSV73379615; called by muse, mutect2, varscan2
- ATP2B1 | c.3276G>T p.E1092D | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.107); called by muse, mutect2
- MAP2K4 | c.740_743del p.D247Afs*28 | Frame Shift Del (DEL) | VAF 31/108 reads (29%) | called by mutect2, pindel, varscan2
- SEC31A | c.3173del p.P1058Qfs*62 (on ENST00000355196 / NM_001318120.1; = p.P1019Qfs*62 on NM_016211.4) | Frame Shift Del (DEL) | VAF 86/255 reads (34%) | called by mutect2, pindel, varscan2
- SOX9 | c.1134_1135dup p.A379Gfs*5 | Frame Shift Ins (INS) | VAF 11/19 reads (58%) | called by mutect2, pindel, varscan2
- ALDH1L1 | c.2433C>T p.I811= | Silent (SNP) | VAF 45/125 reads (36%) | catalogued as rs772215450, COSV56416918; called by muse, mutect2, varscan2
- AMPH | c.1599A>G p.T533= | Silent (SNP) | VAF 39/129 reads (30%) | catalogued as COSV57750519; called by muse, mutect2, varscan2
- CACHD1 | c.2802G>A p.A934= | Silent (SNP) | VAF 41/133 reads (31%) | catalogued as rs368306892; called by muse, mutect2, varscan2
- FGD1 | c.1032C>T p.D344= | Silent (SNP) | VAF 27/39 reads (69%) | catalogued as rs755410522, COSV64309241, COSV99056185; called by muse, mutect2, varscan2
- LDHA | c.162C>T p.I54= | Silent (SNP) | VAF 40/110 reads (36%) | catalogued as rs200075826, COSV57041553; ClinVar: likely benign; called by muse, mutect2, varscan2
- LILRA6 | c.375C>A p.T125= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs761409413; called by muse, mutect2, varscan2
- NVL | c.537A>C p.P179= | Silent (SNP) | VAF 49/155 reads (32%) | catalogued as COSV55874541; called by muse, mutect2, varscan2
- PCDHGA6 | c.1977G>A p.T659= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV53970151; called by muse, mutect2, varscan2
- PCDHGB2 | c.1080G>A p.S360= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV53957153; called by muse, mutect2, varscan2
- PLPP4 | c.489C>A p.G163= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as rs371267002, COSV64828868; called by muse, mutect2, varscan2
- PRAMEF18 | c.753C>T p.S251= | Silent (SNP) | VAF 94/515 reads (18%) | called by muse, mutect2, varscan2
- REV3L | c.9085C>A p.R3029= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV62621461; called by muse, mutect2, varscan2
- SETD1A | c.4821C>T p.A1607= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs770747269, COSV99353787; called by muse, mutect2, varscan2
- SIGLEC8 | c.1092C>T p.V364= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as rs373773537; called by muse, mutect2, varscan2
- SPNS1 | c.528C>T p.A176= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as rs749187043, COSV57955790; called by muse, mutect2, varscan2
- TAS2R8 | c.315C>A p.V105= | Silent (SNP) | VAF 50/133 reads (38%) | catalogued as rs201347044, COSV53690058; called by muse, mutect2, varscan2
- ZNF536 | c.1368C>T p.G456= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs756832106, COSV62829626; called by muse, mutect2, varscan2
- HERC2P3 | n.1779G>A | RNA (SNP) | VAF 34/94 reads (36%) | catalogued as rs551801355; called by muse, mutect2, varscan2
- TGFB2 | c.346+16343C>A | Intron (SNP) | VAF 13/64 reads (20%) | catalogued as COSV65110017, COSV65110227; called by muse, mutect2, varscan2
